Somatic mutation profile of tumor specimen C3N-01842-01 (aliquot CPT0098130009) from CPTAC case C3N-01842, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.9 years (25,527 days).
Specimen C3N-01842-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa383d62-bf68-4cd5-a444-54d7b9b57542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01842-31 (Blood Derived Normal), aliquot CPT0098170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e21c181-0e4f-4657-bb36-db6e38358169

The open-access MAF lists 515 somatic variants for this specimen: 354 protein-altering or splice-affecting, 112 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 296, Silent 112, Nonsense Mutation 21, Intron 18, Frame Shift Del 14, RNA 12, Splice Site 12, 5'Flank 8, Frame Shift Ins 7, 3'UTR 6, Splice Region 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/538 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 59/222 reads (27%) | catalogued as rs730881970, CM041079, COSV58822821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 51/176 reads (29%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99765162; called by muse, mutect2, varscan2
- ACTN2 | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 202/666 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV63976559; called by muse, mutect2, varscan2
- AHNAK | c.9982G>T p.D3328Y | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57215939; called by muse, mutect2, varscan2
- AKAP4 | c.2524del p.A842Pfs*23 | Frame Shift Del (DEL) | VAF 44/131 reads (34%) | catalogued as COSV62073502; called by mutect2, pindel, varscan2
- AL035460.1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.019); catalogued as rs374163831; called by muse, mutect2, varscan2
- ANPEP | c.408G>T p.R136S | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV100263418; called by muse, mutect2, varscan2
- ARMC5 | c.475+1G>T p.X159_splice | Splice Site (SNP) | VAF 65/319 reads (20%) | catalogued as COSV51657284, COSV51658704; called by muse, mutect2, varscan2
- ASPM | c.3875G>T p.R1292I | Missense Mutation (SNP) | VAF 163/512 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV54135266; called by muse, mutect2, varscan2
- BEND2 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1158665367; called by muse, mutect2, varscan2
- BTBD3 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54777963; called by muse, mutect2, varscan2
- C1orf167 | c.2986G>A p.G996S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV100453592; called by muse, mutect2, varscan2
- CCDC185 | c.1593C>A p.H531Q | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs781545110; called by muse, mutect2, varscan2
- CDH4 | c.579C>A p.I193= | Splice Region (SNP) | VAF 41/111 reads (37%) | catalogued as COSV100848168; called by muse, mutect2, varscan2
- CDH8 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54894276; called by muse, mutect2, varscan2
- CEP128 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55388616; called by muse, mutect2, varscan2
- CFAP47 | c.2632C>G p.R878G | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV52881110; called by muse, mutect2, varscan2
- CNTNAP2 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV100663087, COSV100669189; called by muse, mutect2, varscan2
- COL19A1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.211); catalogued as COSV59576580; called by muse, varscan2
- CSMD3 | c.2519C>A p.P840Q (on ENST00000297405 / NM_001363185.1; = p.P736Q on NM_052900.3) | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52205976, COSV99826451; called by muse, varscan2
- CSNK1G1 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs146726850; called by muse, mutect2
- DNAH8 | c.10037G>C p.C3346S | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59455009; called by muse, mutect2, varscan2
- DPP10 | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59674030, COSV59677520; called by muse, mutect2, varscan2
- DSG1 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 128/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57135430; called by muse, mutect2, varscan2
- EIF2B3 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs528321143; called by muse, mutect2, varscan2
- ELP4 | c.242del p.G81Efs*5 | Frame Shift Del (DEL) | VAF 48/281 reads (17%) | catalogued as COSV63359076; called by mutect2, pindel, varscan2
- ENDOD1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as rs200109009; called by muse, mutect2, varscan2
- EPB41L3 | c.2045C>A p.P682Q | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as COSV59458346; called by muse, mutect2, varscan2
- EXOC2 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs748673102; called by muse, mutect2, varscan2
- FAM83C | c.1583C>A p.T528N | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV65582086, COSV65582914; called by muse, mutect2, varscan2
- FBXO40 | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.59); catalogued as rs549329473; called by muse, mutect2
- FGF13 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59542795, COSV59548620; called by muse, mutect2, varscan2
- FHOD3 | c.1849G>A p.E617K (on ENST00000359247 / NM_001281739.3; = p.E634K on NM_025135.5) | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as rs1044726015, COSV57182747; called by muse, mutect2, varscan2
- FLRT2 | c.1741C>G p.R581G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58150971; called by muse, mutect2
- FZD5 | c.480del p.R161Gfs*40 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs1413162495; called by mutect2, pindel, varscan2
- GCN1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100326172, COSV56110687; called by muse, mutect2, varscan2
- GFM1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 152/371 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99962907; called by muse, mutect2, varscan2
- GGN | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs1251713809; called by muse, mutect2
- HCN1 | c.2456T>G p.V819G | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs777848314; called by muse, mutect2, varscan2
- HCN1 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 87/790 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57515702; called by muse, mutect2, varscan2
- HECW1 | c.3897C>A p.F1299L | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV67828547, COSV67835858; called by muse, mutect2, varscan2
- HPX | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1176468921; called by muse, mutect2, varscan2
- HSD17B8 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs766764231, COSV100761872; called by muse, mutect2, varscan2
- IPO4 | c.1805C>A p.A602E | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV61016301; called by muse, mutect2, varscan2
- IQGAP2 | c.3760C>A p.L1254I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs1208461174; called by muse, mutect2, varscan2
- IRX1 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV57360790; called by muse, mutect2, varscan2
- IRX3 | c.706dup p.E236Gfs*12 | Frame Shift Ins (INS) | VAF 32/164 reads (20%) | catalogued as rs761463912; called by mutect2, varscan2
- JAKMIP3 | c.389A>T p.K130M | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309967545, COSV100060152; called by muse, mutect2, varscan2
- KLK2 | c.494-1G>C p.X165_splice | Splice Site (SNP) | VAF 17/126 reads (13%) | catalogued as COSV57570219; called by muse, mutect2, varscan2
- KRTAP9-1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT deleterious (0.02); catalogued as rs978122141; called by muse, mutect2, varscan2
- LCK | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100288261; called by muse, mutect2, varscan2
- LHX5 | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV99922396; called by muse, mutect2, varscan2
- LRFN5 | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99985070; called by muse, mutect2, varscan2
- MDN1 | c.5254G>T p.E1752* | Nonsense Mutation (SNP) | VAF 118/593 reads (20%) | catalogued as COSV101021307, COSV101021969; called by muse, mutect2, varscan2
- MFN1 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1057461661, COSV99764474; called by muse, varscan2
- MS4A12 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs1026503494; called by muse, mutect2, varscan2
- MUC16 | c.26537C>G p.S8846* | Nonsense Mutation (SNP) | VAF 73/238 reads (31%) | catalogued as rs144604762, COSV67476106; called by mutect2, varscan2
- MUC5AC | c.15702C>A p.Y5234* | Nonsense Mutation (SNP) | VAF 52/304 reads (17%) | catalogued as COSV100611599; called by muse, mutect2, varscan2
- MUC6 | c.3145C>A p.L1049I | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as CM142492, COSV70139507; called by muse, mutect2, varscan2
- N4BP1 | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 58/497 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs759263199; called by muse, mutect2, varscan2
- NBEAL1 | c.7566G>T p.Q2522H | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV68916308; called by muse, varscan2
- NCOA2 | c.4314G>T p.R1438S | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); catalogued as COSV99144888; called by muse, mutect2, varscan2
- NDE1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs772376482, COSV61272291, COSV61273690; called by muse, mutect2, varscan2
- NEDD4 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs377587799; called by muse, mutect2, varscan2
- NLRP4 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.127); catalogued as rs267605697, COSV56714710; called by muse, mutect2, varscan2
- NOBOX | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs1341506150; called by muse, mutect2, varscan2
- NYAP1 | c.1364A>T p.D455V | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs959708774; called by muse, mutect2, varscan2
- OPRM1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57676459, COSV57676690; called by mutect2, varscan2
- OR2T33 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 92/618 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100531658; called by muse, varscan2
- OR2T33 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 291/1394 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs769524761; called by muse, varscan2
- OR51D1 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 153/632 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62914745; called by muse, mutect2, varscan2
- OR51E2 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as COSV67808398; called by muse, mutect2, varscan2
- OR52K2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs370060462; called by muse, mutect2, varscan2
- OR5T3 | c.287A>T p.N96I | Missense Mutation (SNP) | VAF 100/405 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57380658; called by muse, mutect2, varscan2
- OR8H3 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV57911253; called by muse, mutect2, varscan2
- OR9A2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100628272; called by muse, mutect2, varscan2
- OSBP | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 52/263 reads (20%) | catalogued as COSV55666015; called by muse, mutect2, varscan2
- OTOG | c.6074G>T p.R2025L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.571); catalogued as rs758497287; called by muse, mutect2, varscan2
- PCDH15 | c.1784+1G>C p.X595_splice | Splice Site (SNP) | VAF 76/410 reads (19%) | catalogued as COSV100217404, COSV100228431; called by muse, mutect2, varscan2
- PDLIM1 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1044607406; called by muse, mutect2
- PMFBP1 | c.2554C>A p.Q852K (on ENST00000537465; = p.Q847K on NM_031293.3) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.954); catalogued as COSV52829933; called by muse, mutect2, varscan2
- POGLUT1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 83/258 reads (32%) | catalogued as COSV55157746; called by muse, mutect2, varscan2
- PRKDC | c.6295G>T p.A2099S | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs773376838; called by muse, mutect2, varscan2
- PRPH | c.972C>A p.C324* | Nonsense Mutation (SNP) | VAF 103/500 reads (21%) | catalogued as rs778838111; called by muse, mutect2, varscan2
- PTPRQ | c.3111G>T p.Q1037H (on ENST00000616559; = p.Q995H on NM_001145026.2) | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as rs1274532719; called by muse, mutect2, varscan2
- RAB11FIP5 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1296944043; called by muse, mutect2, varscan2
- RAG2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 157/759 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57558181; called by muse, mutect2, varscan2
- RBFOX3 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV70555392; called by mutect2, varscan2
- RBM15 | c.2618C>G p.S873C | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV63922951; called by muse, mutect2, varscan2
- RCOR1 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51768821; called by muse, mutect2, varscan2
- RDH10 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV53583306; called by muse, mutect2
- RNASE10 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1264371723; called by muse, mutect2, varscan2
- RYR3 | c.10588G>A p.D3530N (on ENST00000389232; = p.D3531N on NM_001036.6) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV101213469; called by muse, mutect2, varscan2
- SBSN | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 138/1300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1175255565; called by muse, varscan2
- SCN10A | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs766854459; called by muse, mutect2, varscan2
- SEC24D | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99756134; called by muse, mutect2, varscan2
- SEMA3E | c.2057A>T p.D686V | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs371910815; called by muse, mutect2, varscan2
- SIGLEC12 | c.1454C>A p.A485D (on ENST00000291707 / NM_053003.4; = p.A367D on NM_033329.2) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV52466613; called by muse, mutect2, varscan2
- SLC13A1 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52016238; called by muse, mutect2, varscan2
- SLC9A2 | c.1877C>A p.A626D | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as rs1393376411, COSV52131809; called by muse, mutect2, varscan2
- SLITRK4 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024000, COSV62025364; called by muse, mutect2, varscan2
- SLITRK6 | c.1745T>A p.L582H | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV68391706; called by muse, mutect2, varscan2
- SNTG1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as COSV52454596; called by muse, mutect2, varscan2
- SPDYE5 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 89/426 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.161); catalogued as COSV71596506; called by muse, varscan2
- SPDYE5 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 96/706 reads (14%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.161); catalogued as COSV71596085; called by muse, varscan2
- SPINK4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV65688008; called by muse, mutect2, varscan2
- SULF2 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63414485; called by muse, mutect2, varscan2
- TGFBI | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as CM033817, COSV100526410; called by muse, mutect2, varscan2
- TNR | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 44/230 reads (19%) | catalogued as COSV54874117, COSV54876378; called by mutect2, varscan2
- TRIAP1 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.689); catalogued as rs368215298; called by muse, mutect2, varscan2
- TRIM32 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 205/381 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs750300057, COSV57810887; called by muse, mutect2, varscan2
- TRIM58 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as rs748644685, COSV63570293; called by muse, mutect2, varscan2
- TRPM5 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs559213664; called by muse, mutect2, varscan2
- TXNDC16 | c.598A>T p.S200C | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV55987557; called by muse, mutect2, varscan2
- VCAN | c.9367C>A p.Q3123K | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1488969965; called by muse, mutect2, varscan2
- WT1 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 97/522 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV60068942, COSV60085982; called by mutect2, varscan2
- ZBTB46 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs1413583270, COSV99828818; called by muse, mutect2, varscan2
- ZNF527 | c.1689del p.H564Ifs*6 | Frame Shift Del (DEL) | VAF 237/537 reads (44%) | catalogued as rs1483366071; called by mutect2, pindel, varscan2
- ZNF546 | c.85-1G>T p.X29_splice | Splice Site (SNP) | VAF 95/789 reads (12%) | catalogued as rs867735093; called by muse, mutect2, varscan2
- ZNF615 | c.1679G>C p.R560P | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100943875, COSV65033109; called by muse, mutect2, varscan2
- ZP1 | c.304del p.H102Tfs*11 | Frame Shift Del (DEL) | VAF 52/229 reads (23%) | catalogued as COSV99612727; called by mutect2, pindel, varscan2
- ZZZ3 | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66231793; called by muse, mutect2, varscan2
- AARS2 | c.2912A>C p.E971A | Missense Mutation (SNP) | VAF 94/506 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by mutect2, varscan2
- ABCA8 | c.1464del p.E488Dfs*9 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1212del p.R405Efs*12 | Frame Shift Del (DEL) | VAF 72/217 reads (33%) | called by mutect2, pindel, varscan2
- ACACB | c.3195G>A p.M1065I | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ACACB | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACACB | c.6960G>C p.K2320N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ACSL4 | c.1649G>C p.W550S (on ENST00000340800 / NM_022977.2; = p.W509S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ADAMTS16 | c.2062T>A p.F688I | Missense Mutation (SNP) | VAF 166/330 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ADCY8 | c.3646A>C p.N1216H | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADGRD2 | c.2759-1G>T p.X920_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- ADGRG1 | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AGRN | c.4947A>T p.R1649S | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AOC1 | c.1721dup p.K575* | Frame Shift Ins (INS) | VAF 30/166 reads (18%) | called by mutect2, varscan2
- AP2A2 | c.2303A>G p.N768S | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP1 | c.832C>A p.Q278K (on ENST00000393609 / NM_001040118.2; = p.Q33K on NM_015242.4) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARFGEF3 | c.3736G>C p.E1246Q | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASCC1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ATG2A | c.3465del p.R1155Sfs*38 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, varscan2
- ATG2A | c.3465-1G>T p.X1155_splice | Splice Site (SNP) | VAF 13/83 reads (16%) | called by mutect2, varscan2
- ATP11C | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- BAHCC1 | c.62A>T p.H21L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- BARHL2 | c.63T>A p.S21R | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, varscan2
- BBS10 | c.2020A>T p.S674C | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BICD1 | c.1212T>A p.H404Q | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C10orf90 | c.1938G>T p.K646N | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2CD2L | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- C6 | c.2187G>C p.E729D | Missense Mutation (SNP) | VAF 188/405 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CAPN6 | c.1726A>G p.I576V | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC198 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD6 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDAN1 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CDH22 | c.1718A>C p.D573A | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CDH5 | c.1736dup p.N579Kfs*176 | Frame Shift Ins (INS) | VAF 175/825 reads (21%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CDHR5 | c.312+1G>T p.X104_splice | Splice Site (SNP) | VAF 47/229 reads (21%) | called by muse, mutect2, varscan2
- CDRT15L2 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2
- CEP192 | c.6760G>T p.E2254* | Nonsense Mutation (SNP) | VAF 92/417 reads (22%) | called by muse, mutect2, varscan2
- CERS3 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CERS3 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP44 | c.2619G>T p.L873F | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CFAP61 | c.2296C>A p.H766N | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CFAP65 | c.3430C>A p.P1144T | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD7 | c.3913G>T p.G1305C | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CLN5 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNTNAP5 | c.291C>A p.Y97* | Nonsense Mutation (SNP) | VAF 73/315 reads (23%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2358C>A p.D786E | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL24A1 | c.3974del p.R1325Kfs*13 | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel*, varscan2
- COPB2 | c.93G>T p.L31F | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRB1 | c.4057G>T p.V1353F | Missense Mutation (SNP) | VAF 138/845 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBL2 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CSNK1E | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTDP1 | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 84/504 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTSK | c.619-4C>T | Splice Region (SNP) | VAF 99/523 reads (19%) | called by muse, mutect2, varscan2
- CWH43 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- CXorf66 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, varscan2
- CYP2A13 | c.347T>A p.V116E | Missense Mutation (SNP) | VAF 168/327 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, varscan2
- DENND1B | c.177G>C p.R59S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.264); called by muse, mutect2
- DENND2A | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAAF6 | c.73A>T p.S25C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DNAH8 | c.9515C>T p.T3172I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DYNC1H1 | c.10079+1G>T p.X3360_splice | Splice Site (SNP) | VAF 107/539 reads (20%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.885C>A p.F295L | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- EPB41L3 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPC1 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ESPN | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 84/427 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYS | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- FAM47A | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, varscan2
- FAM71E2 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FBF1 | c.917A>C p.Q306P (on ENST00000586717; = p.Q320P on NM_001319193.1) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FBN2 | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 148/507 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBXO44 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.1402A>G p.R468G (on ENST00000354552 / NM_182909.3; = p.R228G on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/467 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLNC | c.3263A>G p.K1088R | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FO393400.1 | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 26/100 reads (26%) | called by mutect2, varscan2
- FO393400.1 | c.1delinsCT p.M1? | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2*, pindel, varscan2*
- FSIP2 | c.12717C>A p.S4239R | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- FSTL5 | c.1436G>C p.S479T | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- FZD10 | c.1609C>G p.R537G | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- G2E3 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- GALNT17 | c.662A>T p.Q221L | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GAREM2 | c.623C>A p.P208Q | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- GCM1 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJB6 | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 137/391 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLI4 | c.602A>T p.H201L | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLRX5 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPATCH1 | c.1586-2A>T p.X529_splice | Splice Site (SNP) | VAF 132/244 reads (54%) | called by muse, varscan2
- GPR85 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- GPRC6A | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HCN4 | c.3442C>A p.Q1148K | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HEATR1 | c.3730G>T p.E1244* | Nonsense Mutation (SNP) | VAF 52/299 reads (17%) | called by muse, mutect2, varscan2
- HEATR6 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPHL1 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HEXIM2 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- HLTF | c.1023dup p.G342Wfs*7 | Frame Shift Ins (INS) | VAF 90/343 reads (26%) | called by mutect2, pindel, varscan2
- HMGCS1 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 88/469 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HOXB3 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HOXD13 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYOU1 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- IL1RAPL1 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IL1RAPL2 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IL21R | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCK | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IQSEC1 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- JAKMIP2 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNA2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNC1 | c.1443C>A p.H481Q | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNG3 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 100/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH7 | c.2339C>A p.T780N | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- KDM4B | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- KIAA0513 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1210 | c.2509C>T p.L837F | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF25 | c.659G>C p.C220S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL13 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LCE3E | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 173/498 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- LIMS1 | c.156+3G>T | Splice Region (SNP) | VAF 57/340 reads (17%) | called by muse, mutect2, varscan2
- LIMS2 | c.986G>T p.R329L (on ENST00000355119 / NM_001161403.3; = p.R353L on NM_017980.4) | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LIPC | c.1223T>C p.V408A | Missense Mutation (SNP) | VAF 129/535 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC37A3 | c.4209G>C p.M1403I | Missense Mutation (SNP) | VAF 146/739 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LRRC69 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC74B | c.1163C>A p.A388E | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- LSS | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MFSD6L | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, varscan2
- MGAM2 | c.6260C>A p.T2087K | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- MKI67 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MPP7 | c.768C>G p.F256L | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSL1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MXRA5 | c.2450T>A p.V817D | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYO18B | c.3931G>T p.V1311L | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYRF | c.394C>G p.P132A (on ENST00000278836 / NM_001127392.3; = p.P123A on NM_013279.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- MYT1 | c.2113A>T p.S705C | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- NALCN | c.1622C>A p.P541Q | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NARS1 | c.579+1G>T p.X193_splice | Splice Site (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- NGEF | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NOTUM | c.182del p.G61Vfs*39 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by mutect2, varscan2
- NT5DC4 | c.44_51del p.K15Mfs*19 | Frame Shift Del (DEL) | VAF 45/389 reads (12%) | called by mutect2, pindel, varscan2
- NUP205 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OGDHL | c.208T>A p.W70R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T11 | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR2T27 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR2T8 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR4C11 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- OR5D16 | c.709del p.R237Afs*11 | Frame Shift Del (DEL) | VAF 60/321 reads (19%) | called by mutect2, pindel, varscan2
- OR5D18 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- OTOGL | c.2435G>T p.G812V (on ENST00000547103; = p.G803V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- OTULIN | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 234/448 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PAPOLG | c.1120A>T p.I374L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PATJ | c.5177G>T p.R1726L | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA6 | c.968_970delinsAA p.T323Kfs*15 | Frame Shift Del (DEL) | VAF 63/306 reads (21%) | called by pindel, varscan2*
- PCDHB12 | c.2286T>A p.N762K | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCD10 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 59/331 reads (18%) | called by muse, mutect2, varscan2
- PLXNA2 | c.4783G>C p.V1595L | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PLXNA4 | c.2257C>A p.L753M | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PNPLA6 | c.2336C>T p.A779V (on ENST00000414982 / NM_001166111.2; = p.A731V on NM_006702.5) | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- POU6F2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPM1D | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R14B | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PRAMEF19 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by mutect2, varscan2
- PRDM2 | c.3644C>A p.P1215Q | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRDM9 | c.1626C>A p.H542Q | Missense Mutation (SNP) | VAF 460/874 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PRKD3 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS56 | c.1703C>A p.A568E | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PTPN22 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRQ | c.4066C>A p.R1356S (on ENST00000616559; = p.R1314S on NM_001145026.2) | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYGO2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB4A | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- RALGAPA1 | c.4597G>A p.V1533M | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RBM14 | c.1321G>C p.A441P | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RFPL4AL1 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RFX6 | c.2750A>G p.N917S | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RIMS2 | c.3635A>T p.D1212V | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); called by muse, varscan2
- RNF115 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RNF186 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- RPL8 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RRP12 | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | called by muse, varscan2
- RTL3 | c.984C>A p.C328* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | called by muse, mutect2, varscan2
- RYR3 | c.11248C>T p.Q3750* (on ENST00000389232; = p.Q3751* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 66/155 reads (43%) | called by muse, mutect2, varscan2
- SCIN | c.325A>G p.S109G | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN10A | c.4894G>C p.V1632L | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDK1 | c.3246C>A p.S1082R | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SEMA5A | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 32/684 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.201); called by muse, mutect2
- SH2D3C | c.1257del p.Y419* (on ENST00000314830 / NM_170600.3; = p.Y262* on NM_005489.4) | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | called by mutect2, pindel, varscan2
- SHLD1 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SHPRH | c.2425G>C p.V809L | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SI | c.5401G>A p.D1801N | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLAMF7 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLAMF7 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A3 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A8 | c.1258A>T p.I420F | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMARCAL1 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 143/606 reads (24%) | called by muse, mutect2, varscan2
- SOX2 | c.544dup p.Q182Pfs*128 | Frame Shift Ins (INS) | VAF 49/243 reads (20%) | called by mutect2, pindel, varscan2
- SPAG4 | c.503T>C p.F168S | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTB | c.6615C>A p.N2205K | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SPTBN5 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 76/354 reads (21%) | PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- STAG1 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- STAP1 | c.730-1G>A p.X244_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- SUSD4 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SUSD4 | c.1347C>A p.C449* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- THUMPD1 | c.530A>T p.K177I | Missense Mutation (SNP) | VAF 72/374 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TMEM209 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TMPRSS15 | c.1884A>T p.K628N | Missense Mutation (SNP) | VAF 369/918 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TOP2B | c.3915G>T p.R1305S (on ENST00000264331 / NM_001330700.2; = p.R1300S on NM_001068.3) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRAV8-4 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2
- TRERF1 | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM48 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 120/563 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TSPOAP1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.50416C>A p.P16806T (on ENST00000591111; = p.P9382T on NM_003319.4) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | PolyPhen benign (0.322); called by muse, mutect2, varscan2
- TXLNB | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- UBAP2L | c.2903-5C>G | Splice Region (SNP) | VAF 43/278 reads (15%) | called by muse, mutect2, varscan2
- UNC13A | c.2570C>A p.T857K | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UNC13A | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UNC13C | c.2340T>G p.H780Q | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UROC1 | c.467T>A p.M156K | Missense Mutation (SNP) | VAF 109/479 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP5 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR72 | c.3004A>T p.K1002* | Nonsense Mutation (SNP) | VAF 56/261 reads (21%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.266T>A p.V89E | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- XPO5 | c.29G>C p.C10S | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZDBF2 | c.3112G>T p.G1038C | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF212 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 91/468 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF239 | c.800A>T p.K267M | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF534 | c.1285G>T p.G429C (on ENST00000332323 / NM_001143939.3; = p.G416C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF609 | c.3050A>T p.Q1017L | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF644 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF681 | c.1825A>T p.K609* | Nonsense Mutation (SNP) | VAF 45/214 reads (21%) | called by muse, mutect2, varscan2
- ZNF729 | c.3380C>G p.T1127S | Missense Mutation (SNP) | VAF 87/509 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF804A | c.1691C>T p.T564I | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF99 | c.2483G>T p.W828L | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, varscan2
- ZNF99 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 150/605 reads (25%) | called by muse, mutect2, varscan2
- ZNF99 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 103/494 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSL5 | c.984C>T p.F328= (on ENST00000354273; = p.F384= on NM_016234.3) | Silent (SNP) | VAF 64/254 reads (25%) | called by muse, mutect2, varscan2
- ACTN1 | c.1374A>T p.A458= | Silent (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- ADAMTS1 | c.399C>A p.P133= | Silent (SNP) | VAF 70/228 reads (31%) | called by muse, mutect2, varscan2
- ADGRG5 | c.1335G>A p.A445= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as rs373117228; called by muse, mutect2, varscan2
- AIF1L | c.285G>T p.V95= | Silent (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2649C>A p.A883= (on ENST00000611781; = p.A827= on NM_052997.2) | Silent (SNP) | VAF 104/586 reads (18%) | catalogued as COSV100652725; called by muse, mutect2, varscan2
- ANKRD55 | c.1275C>A p.A425= | Silent (SNP) | VAF 38/259 reads (15%) | called by mutect2, varscan2
- APMAP | c.819G>T p.V273= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- APOA1 | c.600G>A p.A200= | Silent (SNP) | VAF 70/302 reads (23%) | called by muse, mutect2, varscan2
- ASPHD2 | c.577C>A p.R193= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as COSV53218716; called by muse, mutect2, varscan2
- BSG | c.495G>A p.E165= | Silent (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2, varscan2
- CARTPT | c.111C>T p.A37= | Silent (SNP) | VAF 42/440 reads (10%) | called by muse, mutect2
- CCR6 | c.1072C>A p.R358= | Silent (SNP) | VAF 56/216 reads (26%) | catalogued as COSV59474125; called by muse, mutect2
- CDH23 | c.3144C>A p.R1048= | Silent (SNP) | VAF 26/246 reads (11%) | catalogued as rs372927470; called by muse, varscan2
- CFAP46 | c.3912G>A p.V1304= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1483848784; called by muse, mutect2, varscan2
- CHRNA4 | c.1695C>A p.T565= | Silent (SNP) | VAF 71/229 reads (31%) | called by muse, mutect2, varscan2
- CHST3 | c.99A>T p.I33= | Silent (SNP) | VAF 127/552 reads (23%) | called by muse, mutect2, varscan2
- CNNM4 | c.303C>T p.T101= | Silent (SNP) | VAF 58/277 reads (21%) | called by muse, mutect2, varscan2
- COL6A5 | c.6276G>A p.E2092= (on ENST00000312481; = p.E2088= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/266 reads (26%) | called by muse, mutect2, varscan2
- CSE1L | c.2637C>T p.P879= | Silent (SNP) | VAF 33/334 reads (10%) | catalogued as rs892503381; called by muse, mutect2, varscan2
- CSK | c.1002T>A p.G334= | Silent (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2781G>A p.P927= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs768964682; called by muse, mutect2, varscan2
- DPP8 | c.2040G>T p.R680= (on ENST00000341861 / NM_001320875.2; = p.R664= on NM_130434.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- DPYS | c.1559G>A p.*520= | Silent (SNP) | VAF 68/347 reads (20%) | catalogued as COSV100679858, COSV60914351; called by muse, mutect2, varscan2
- EPB41L2 | c.669C>G p.T223= | Silent (SNP) | VAF 14/353 reads (4%) | called by muse, mutect2
- F13A1 | c.492C>A p.V164= | Silent (SNP) | VAF 112/858 reads (13%) | called by mutect2, varscan2
- FAM126B | c.57A>G p.L19= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as rs372235427; called by muse, mutect2, varscan2
- FAM71E2 | c.1884C>A p.T628= | Silent (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- FANCA | c.315G>T p.L105= | Silent (SNP) | VAF 171/614 reads (28%) | catalogued as COSV66882568; called by mutect2, varscan2
- FEZ1 | c.807C>T p.S269= | Silent (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.925C>T p.L309= (on ENST00000253928 / NM_001308068.2; = p.L308= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/404 reads (20%) | catalogued as rs747322764; called by muse, mutect2, varscan2
- FOXJ3 | c.213C>A p.V71= | Silent (SNP) | VAF 108/465 reads (23%) | called by muse, mutect2, varscan2
- FSCN1 | c.822C>T p.S274= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as rs906481719; called by muse, mutect2, varscan2
- GCN1 | c.5694G>T p.L1898= | Silent (SNP) | VAF 72/370 reads (19%) | called by muse, mutect2, varscan2
- GDF10 | c.1378C>A p.R460= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- GH2 | c.450G>T p.L150= | Silent (SNP) | VAF 60/331 reads (18%) | called by muse, mutect2, varscan2
- GPR26 | c.552C>G p.S184= | Silent (SNP) | VAF 29/312 reads (9%) | called by muse, mutect2
- GPR45 | c.459G>T p.A153= | Silent (SNP) | VAF 76/354 reads (21%) | catalogued as COSV99307115; called by muse, mutect2, varscan2
- HCN1 | c.1038A>T p.S346= | Silent (SNP) | VAF 453/861 reads (53%) | called by muse, mutect2, varscan2
- HECTD4 | c.9072C>T p.F3024= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as rs1228471770; called by muse, mutect2, varscan2
- HMCN2 | c.14539C>A p.R4847= | Silent (SNP) | VAF 54/244 reads (22%) | called by muse, mutect2, varscan2
- HYOU1 | c.99G>T p.L33= | Silent (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- IFT140 | c.3192C>T p.P1064= | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as rs376962964; called by muse, mutect2, varscan2
- IGF1R | c.150G>A p.E50= | Silent (SNP) | VAF 96/422 reads (23%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.18T>C p.P6= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs1197813644; called by muse, mutect2, varscan2
- IL12RB1 | c.732G>T p.S244= | Silent (SNP) | VAF 202/531 reads (38%) | catalogued as rs145487261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KALRN | c.2181C>A p.S727= | Silent (SNP) | VAF 64/413 reads (15%) | called by muse, varscan2
- KAZALD1 | c.186C>T p.A62= | Silent (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- KCNH1 | c.2328C>A p.A776= (on ENST00000271751 / NM_172362.3; = p.A749= on NM_002238.4) | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV55091513; called by muse, mutect2, varscan2
- KLHDC7B | c.1386C>T p.R462= (on ENST00000395676; = p.R1103= on NM_138433.5) | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs766495674; called by muse, mutect2, varscan2
- LEP | c.355T>C p.L119= | Silent (SNP) | VAF 92/382 reads (24%) | called by muse, mutect2, varscan2
- LTBP1 | c.144C>A p.P48= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- MAP7D2 | c.1378C>A p.R460= | Silent (SNP) | VAF 131/274 reads (48%) | catalogued as rs757262581, COSV65530004; called by muse, mutect2, varscan2
- MAPK7 | c.651C>T p.F217= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV55189630; called by muse, mutect2, varscan2
- MAST4 | c.3738G>T p.R1246= (on ENST00000403625 / NM_001164664.2; = p.R1057= on NM_015183.3) | Silent (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- MIXL1 | c.84G>C p.A28= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV64729332; called by muse, mutect2, varscan2
- MOCS3 | c.552C>T p.P184= | Silent (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- MPIG6B | c.708C>T p.I236= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as rs987848196; called by muse, mutect2
- MROH6 | c.726A>G p.T242= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs1338708176; called by muse, mutect2, varscan2
- MUTYH | c.1206G>T p.P402= | Silent (SNP) | VAF 91/389 reads (23%) | catalogued as rs876659935; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH1 | c.3654G>A p.K1218= | Silent (SNP) | VAF 72/293 reads (25%) | called by muse, mutect2, varscan2
- NMBR | c.175C>T p.L59= | Silent (SNP) | VAF 44/468 reads (9%) | called by muse, mutect2
- NOL4L | c.1206G>A p.T402= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs144695451; called by muse, mutect2, varscan2
- NRXN2 | c.3954C>A p.L1318= | Silent (SNP) | VAF 88/417 reads (21%) | called by muse, varscan2
- NSF | c.1890G>T p.L630= | Silent (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- OR2M4 | c.822G>T p.V274= | Silent (SNP) | VAF 113/380 reads (30%) | catalogued as rs1461317754; called by muse, mutect2, varscan2
- OR8D4 | c.171C>G p.T57= | Silent (SNP) | VAF 60/243 reads (25%) | catalogued as COSV100361687; called by muse, mutect2, varscan2
- PADI2 | c.444G>T p.G148= | Silent (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- PFKP | c.711G>T p.V237= | Silent (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- PGK2 | c.849T>A p.P283= | Silent (SNP) | VAF 112/438 reads (26%) | called by muse, mutect2, varscan2
- PGR | c.465C>G p.P155= | Silent (SNP) | VAF 39/233 reads (17%) | catalogued as COSV54795535; called by muse, mutect2, varscan2
- PHF8 | c.2391G>T p.G797= (on ENST00000357988 / NM_001184896.1; = p.G761= on NM_015107.3) | Silent (SNP) | VAF 82/178 reads (46%) | called by muse, varscan2
- PIGK | c.27G>T p.R9= | Silent (SNP) | VAF 73/343 reads (21%) | called by muse, mutect2, varscan2
- PKHD1 | c.9942C>A p.T3314= | Silent (SNP) | VAF 76/424 reads (18%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2910C>G p.T970= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- POP1 | c.1575C>T p.P525= | Silent (SNP) | VAF 98/446 reads (22%) | called by muse, mutect2, varscan2
- POU3F3 | c.1257C>G p.G419= | Silent (SNP) | VAF 65/324 reads (20%) | catalogued as COSV63722002; called by muse, mutect2, varscan2
- PRDX3 | c.375G>T p.V125= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as COSV53720374; called by muse, mutect2, varscan2
- PTGR1 | c.195G>A p.G65= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as COSV99436976; called by muse, mutect2, varscan2
- RIMBP2 | c.2385A>G p.A795= | Silent (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- RNF186 | c.465G>T p.L155= | Silent (SNP) | VAF 71/299 reads (24%) | called by muse, mutect2, varscan2
- ROBO2 | c.2103C>T p.N701= | Silent (SNP) | VAF 58/429 reads (14%) | called by muse, mutect2, varscan2
- RTL1 | c.1563C>A p.G521= | Silent (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2, varscan2
- SEMA5A | c.975C>T p.S325= | Silent (SNP) | VAF 49/323 reads (15%) | catalogued as rs765586378, COSV66787115; called by muse, mutect2, varscan2
- SHANK1 | c.2940G>T p.V980= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- SLC11A2 | c.774G>A p.V258= (on ENST00000394904 / NM_001379455.1; = p.V229= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/412 reads (18%) | catalogued as rs771118729; called by muse, mutect2, varscan2
- SLC43A3 | c.930G>T p.G310= | Silent (SNP) | VAF 66/356 reads (19%) | called by mutect2, varscan2
- SNW1 | c.837C>T p.H279= | Silent (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- SNX7 | c.225A>T p.P75= | Silent (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- SOX11 | c.132G>A p.T44= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV58984067; called by muse, mutect2
- SPTBN5 | c.1035G>C p.L345= | Silent (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- SRPX | c.918C>A p.S306= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV59438927; called by muse, mutect2, varscan2
- SSH1 | c.2946G>C p.L982= | Silent (SNP) | VAF 60/351 reads (17%) | called by muse, mutect2, varscan2
- SYN3 | c.1371C>A p.S457= | Silent (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- SYT3 | c.813G>A p.K271= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- TERT | c.117G>T p.V39= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- THUMPD1 | c.966G>C p.T322= | Silent (SNP) | VAF 63/324 reads (19%) | called by muse, mutect2, varscan2
- TOMM70 | c.1779C>G p.A593= | Silent (SNP) | VAF 106/305 reads (35%) | called by muse, mutect2, varscan2
- TRIM49C | c.906G>T p.L302= | Silent (SNP) | VAF 60/278 reads (22%) | catalogued as COSV101442227; called by mutect2, varscan2
- TRIM64B | c.75G>T p.P25= | Silent (SNP) | VAF 73/570 reads (13%) | catalogued as COSV61693764, COSV61694630; called by muse, mutect2, varscan2
- TRPC7 | c.1107T>C p.Y369= | Silent (SNP) | VAF 48/165 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.46506T>C p.D15502= (on ENST00000591111; = p.D8078= on NM_003319.4) | Silent (SNP) | VAF 128/532 reads (24%) | called by muse, mutect2, varscan2
- UMPS | c.438C>T p.V146= | Silent (SNP) | VAF 116/647 reads (18%) | catalogued as COSV99228777; called by muse, mutect2, varscan2
- VWA3A | c.1941C>T p.F647= | Silent (SNP) | VAF 54/281 reads (19%) | called by muse, mutect2, varscan2
- WT1 | c.762C>A p.P254= | Silent (SNP) | VAF 96/531 reads (18%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.312A>G p.T104= | Silent (SNP) | VAF 40/322 reads (12%) | called by muse, mutect2, varscan2
- YIPF6 | c.273G>A p.L91= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7851G>T p.L2617= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- ZNF33A | c.1500A>G p.A500= (on ENST00000458705 / NM_006974.3; = p.A501= on NM_006954.2) | Silent (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- ZNF469 | c.3261G>T p.R1087= (on ENST00000437464; = p.R1115= on NM_001367624.2) | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as rs991608374; called by muse, mutect2, varscan2
- ZNF804A | c.459A>G p.Q153= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as rs553072965; called by muse, mutect2, varscan2
- ZNF831 | c.4830T>C p.S1610= | Silent (SNP) | VAF 82/360 reads (23%) | called by muse, mutect2, varscan2
- AC002511.3 | chr19:35408593 G>T | 3'Flank (SNP) | VAF 206/325 reads (63%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2432T>C | RNA (SNP) | VAF 56/301 reads (19%) | called by muse, mutect2, varscan2
- AC093791.1 | n.346A>T | RNA (SNP) | VAF 51/221 reads (23%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1411G>T | RNA (SNP) | VAF 66/457 reads (14%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1049G>T | RNA (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1191T>C | RNA (SNP) | VAF 171/906 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938409 G>C | 5'Flank (SNP) | VAF 23/255 reads (9%) | catalogued as rs775941461; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916386 G>T | 5'Flank (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- ARMC6 | c.*149G>C | 3'UTR (SNP) | VAF 14/113 reads (12%) | catalogued as rs755918247, COSV54183282; called by muse, mutect2, varscan2
- AZGP1P1 | n.206C>A | RNA (SNP) | VAF 59/340 reads (17%) | catalogued as rs748593338; called by muse, mutect2, varscan2
- BCAS3 | c.2639-3265A>G | Intron (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- CD81 | c.459+11G>T | Intron (SNP) | VAF 70/329 reads (21%) | called by muse, mutect2, varscan2
- CLK2P1 | n.867G>C | RNA (SNP) | VAF 150/716 reads (21%) | called by muse, mutect2, varscan2
- CPEB2 | chr4:15001983 G>A | 5'Flank (SNP) | VAF 14/80 reads (18%) | catalogued as rs1412107060; called by muse, mutect2
- DEPDC4 | c.*14G>A | 3'UTR (SNP) | VAF 23/152 reads (15%) | catalogued as rs776126637; called by muse, mutect2, varscan2
- DNMBP | c.2261-21218G>C | Intron (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- EYS | c.1767-7237C>A | Intron (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- FAM131A | c.*643del | 3'UTR (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- FOXP2 | c.*1815C>T | 3'UTR (SNP) | VAF 25/212 reads (12%) | called by muse, mutect2, varscan2
- GABRG3 | c.1123-1967C>T | Intron (SNP) | VAF 46/198 reads (23%) | called by muse, varscan2
- GDAP1 | c.*1899A>T | 3'UTR (SNP) | VAF 74/363 reads (20%) | called by muse, mutect2, varscan2
- GNPNAT1 | c.345+28C>G | Intron (SNP) | VAF 86/255 reads (34%) | catalogued as rs1419419341; called by muse, mutect2, varscan2
- ITGAX | c.318+52G>T | Intron (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- KRT13 | c.1244+42G>C | Intron (SNP) | VAF 75/304 reads (25%) | called by muse, mutect2, varscan2
- LHX9 | chr1:197917361 C>G | 5'Flank (SNP) | VAF 32/194 reads (16%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+520T>A | Intron (SNP) | VAF 64/192 reads (33%) | called by muse, mutect2, varscan2
- MINDY4 | c.1678-223G>T | Intron (SNP) | VAF 69/399 reads (17%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-110G>T | 5'UTR (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- NAALADL2 | c.43+4640G>T | Intron (SNP) | VAF 84/292 reads (29%) | called by muse, mutect2
- NALCN | c.2118+77G>T | Intron (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- NELL1 | c.56-3415G>T | Intron (SNP) | VAF 56/324 reads (17%) | called by muse, mutect2, varscan2
- OR1D4 | n.453G>T | RNA (SNP) | VAF 105/327 reads (32%) | called by muse, mutect2, varscan2
- OR2L1P | n.893G>T | RNA (SNP) | VAF 40/508 reads (8%) | called by muse, mutect2
- OR4F13P | n.717G>T | RNA (SNP) | VAF 67/346 reads (19%) | called by muse, varscan2
- OR6W1P | n.186A>T | RNA (SNP) | VAF 81/310 reads (26%) | called by muse, mutect2, varscan2
- PPT2 | chr6:32153551 C>A | 5'Flank (SNP) | VAF 57/306 reads (19%) | called by muse, mutect2, varscan2
- PRKRA | c.235+28C>T | Intron (SNP) | VAF 102/435 reads (23%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112220354 C>T | 3'Flank (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- R3HDML | chr20:44355781 C>A | 3'Flank (SNP) | VAF 46/193 reads (24%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790362 T>C | 5'Flank (SNP) | VAF 32/139 reads (23%) | catalogued as rs1335520713; called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892512 G>T | 5'Flank (SNP) | VAF 138/386 reads (36%) | called by muse, mutect2, varscan2
- SKA2 | c.33+3994G>T | Intron (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
- SLC25A45 | c.38-463dup | Intron (INS) | VAF 16/85 reads (19%) | called by mutect2, pindel
- STK11IP | c.-35G>T | 5'UTR (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- SVIL2P | n.1851G>T | RNA (SNP) | VAF 38/361 reads (11%) | called by muse, mutect2, varscan2
- SYT5 | c.*40C>A | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- TPM1 | c.115-514del | Intron (DEL) | VAF 55/324 reads (17%) | called by mutect2, pindel, varscan2
- VEGFA | chr6:43771137 G>T | 5'Flank (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- XKR9 | c.272+2184G>A | Intron (SNP) | VAF 21/106 reads (20%) | catalogued as rs1357934645; called by muse, mutect2, varscan2
